Somatic mutation profile of tumor specimen TCGA-CH-5738-01A (aliquot TCGA-CH-5738-01A-11D-1576-08) from TCGA case TCGA-CH-5738, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.1 years (26,329 days).
Specimen TCGA-CH-5738-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bd238e2-f6cb-4994-bf77-f340b2e3cd00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5738-10A (Blood Derived Normal), aliquot TCGA-CH-5738-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d40d76c1-8929-4d7e-9a09-faf700f43c51

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS1 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.337); catalogued as rs201769018, COSV53169152; called by muse, mutect2
- ASB2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780584539, COSV60110892; called by muse, mutect2, varscan2
- CEMIP | c.3670C>T p.H1224Y | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1388799498, COSV54989341; called by muse, mutect2, varscan2
- DNAH9 | c.11017G>A p.E3673K | Missense Mutation (SNP) | VAF 7/206 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV52339281; called by muse, mutect2
- GARRE1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV55097476; called by muse, mutect2, varscan2
- LRRC37A3 | c.3832G>A p.A1278T | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769893046, COSV58535772; called by muse, mutect2
- MAP1B | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs372421201; called by muse, mutect2, varscan2
- POF1B | c.1238C>A p.S413* | Nonsense Mutation (SNP) | VAF 52/217 reads (24%) | catalogued as COSV53131585; called by muse, mutect2, varscan2
- VSIG8 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs112455697, COSV63652496; called by muse, varscan2
- ZMYM3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV58736648; called by muse, mutect2
- ZNF420 | c.696T>A p.F232L | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58493043; called by muse, mutect2
- FMOD | c.609G>A p.T203= | Silent (SNP) | VAF 81/352 reads (23%) | catalogued as rs374060031, COSV100724538; called by muse, mutect2, varscan2
- LLGL1 | c.561C>T p.D187= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs374218881; called by muse, mutect2, varscan2
- MAGEA6 | c.522C>T p.H174= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs1556826517, COSV61448746, COSV61448773; called by muse, mutect2
- SYN3 | c.687A>G p.T229= | Silent (SNP) | VAF 18/462 reads (4%) | catalogued as COSV56662567; called by muse, mutect2
- CREM | c.891-343G>A | Intron (SNP) | VAF 33/155 reads (21%) | catalogued as rs753307596, COSV59765730; called by muse, mutect2, varscan2
